Somatic mutation profile of tumor specimen C3N-02379-01 (aliquot CPT0146580010) from CPTAC case C3N-02379, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 57.0 years (20,827 days).
Specimen C3N-02379-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cc55643b-923f-4634-9052-9c2a09c2ee2b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02379-71 (Blood Derived Normal), aliquot CPT0146610002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/90b6a32a-cdc5-4f0a-82d3-9271413a3d2b

The open-access MAF lists 79 somatic variants for this specimen: 51 protein-altering or splice-affecting, 20 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, Silent 20, Frame Shift Del 3, Intron 3, Nonsense Mutation 2, 3'UTR 2, 5'UTR 2, In Frame Del 2, Splice Site 1, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 526/989 reads (53%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- RPGRIP1L | c.3446T>A p.I1149N | Missense Mutation (SNP) | VAF 52/244 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs766943204, COSV50907339; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ANO6 | c.1270G>C p.A424P | Missense Mutation (SNP) | VAF 69/427 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV57662893; called by muse, mutect2, varscan2
- DOCK3 | c.892C>T p.R298W | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1334557899; called by muse, mutect2
- GLCCI1 | c.1304G>A p.R435H | Missense Mutation (SNP) | VAF 15/120 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.982); catalogued as rs199991040, COSV56202476, COSV99780404; called by muse, mutect2, varscan2
- LAMA3 | c.3565G>A p.A1189T | Missense Mutation (SNP) | VAF 78/603 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs771491240, COSV58079173; called by muse, varscan2
- MSX1 | c.575G>A p.R192H | Missense Mutation (SNP) | VAF 24/149 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs760914206, COSV101235792; called by muse, mutect2, varscan2
- MYBBP1A | c.1695C>A p.F565L | Missense Mutation (SNP) | VAF 34/124 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.198); catalogued as COSV54598526; called by muse, mutect2, varscan2
- NEXN | c.1190G>A p.R397Q | Missense Mutation (SNP) | VAF 23/325 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as rs201806320, COSV100331086, COSV57357822; ClinVar: uncertain significance; called by muse, mutect2
- OTOP2 | c.367G>A p.G123S | Missense Mutation (SNP) | VAF 49/288 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as rs767255149, COSV58881297; called by muse, mutect2, varscan2
- PHTF1 | c.1589C>T p.S530L | Missense Mutation (SNP) | VAF 18/193 reads (9%) | SIFT tolerated (0.7); PolyPhen benign (0.23); catalogued as rs376954475; called by muse, mutect2
- PRRC2C | c.151G>A p.G51S (on ENST00000367742; = p.G49S on NM_015172.4) | Missense Mutation (SNP) | VAF 17/133 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); catalogued as rs1408902539, COSV58901614; called by muse, mutect2, varscan2
- SALL3 | c.1001C>T p.S334L | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as rs904578012; called by muse, varscan2
- TBC1D16 | c.2192G>C p.G731A | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs1011889144; called by muse, mutect2, varscan2
- TRIT1 | c.65C>G p.T22S | Missense Mutation (SNP) | VAF 27/134 reads (20%) | SIFT tolerated (0.79); PolyPhen benign (0.01); catalogued as rs192151286; called by muse, mutect2, varscan2
- TTK | c.289G>C p.A97P | Missense Mutation (SNP) | VAF 38/232 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.653); catalogued as COSV57885901; called by muse, mutect2, varscan2
- USP27X | c.1026T>G p.S342R | Missense Mutation (SNP) | VAF 86/405 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.012); catalogued as CD151029; called by muse, mutect2, varscan2
- ZNF804A | c.2945G>A p.G982E | Missense Mutation (SNP) | VAF 99/255 reads (39%) | SIFT tolerated (0.56); PolyPhen benign (0.075); catalogued as COSV56435993; called by muse, mutect2, varscan2
- ADAMTS9 | c.2370_2389+9delinsTACTTAGGTGA p.X790_splice | Splice Site (DEL) | VAF 24/212 reads (11%) | called by pindel, varscan2*
- AKT2 | c.1087C>A p.L363I | Missense Mutation (SNP) | VAF 28/360 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.562); called by muse, mutect2
- C12orf73 | c.147_148del p.K49Nfs*22 | Frame Shift Del (DEL) | VAF 22/136 reads (16%) | called by pindel, varscan2
- CD22 | c.1216C>T p.Q406* | Nonsense Mutation (SNP) | VAF 24/94 reads (26%) | called by muse, mutect2, varscan2
- CDK2AP2 | c.132C>G p.F44L | Missense Mutation (SNP) | VAF 24/458 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.566); called by muse, mutect2
- CRYBB2 | c.90C>A p.H30Q | Missense Mutation (SNP) | VAF 87/430 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- CYP24A1 | c.896C>T p.A299V | Missense Mutation (SNP) | VAF 136/404 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DMD | c.8413G>A p.D2805N | Missense Mutation (SNP) | VAF 85/478 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); called by muse, mutect2, varscan2
- DNAJB1 | c.229_243del p.P77_S81del | In Frame Del (DEL) | VAF 8/67 reads (12%) | called by mutect2, pindel
- DPEP2 | c.940T>G p.L314V | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- HHIP | c.1772dup p.E592* | Frame Shift Ins (INS) | VAF 11/47 reads (23%) | called by mutect2, pindel
- KIF4B | c.64A>G p.K22E | Missense Mutation (SNP) | VAF 37/267 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.215); called by muse, mutect2, varscan2
- KRT12 | c.1352C>G p.S451C | Missense Mutation (SNP) | VAF 30/430 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.005); called by muse, mutect2
- LRP5 | c.1888G>T p.G630C | Missense Mutation (SNP) | VAF 18/199 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MLLT10 | c.1841C>G p.A614G (on ENST00000307729 / NM_001195626.3; = p.A630G on NM_004641.3) | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- MTUS1 | c.1630_1632del p.S544del | In Frame Del (DEL) | VAF 31/235 reads (13%) | called by pindel, varscan2
- N4BP1 | c.944C>G p.T315R | Missense Mutation (SNP) | VAF 19/346 reads (5%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2
- OR2T12 | c.473C>A p.A158D | Missense Mutation (SNP) | VAF 22/424 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2
- PCDHA1 | c.458C>T p.P153L | Missense Mutation (SNP) | VAF 7/151 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.192); called by muse, mutect2
- PCDHB14 | c.1790G>A p.G597D | Missense Mutation (SNP) | VAF 49/449 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PCDHGA3 | c.1171C>G p.P391A | Missense Mutation (SNP) | VAF 51/199 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- PLD1 | c.1156G>T p.E386* | Nonsense Mutation (SNP) | VAF 42/168 reads (25%) | called by mutect2, varscan2
- PTPN13 | c.6955T>C p.C2319R (on ENST00000411767 / NM_080683.3; = p.C2300R on NM_006264.3) | Missense Mutation (SNP) | VAF 44/280 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RHOBTB1 | c.1251T>G p.F417L | Missense Mutation (SNP) | VAF 36/178 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- RRP15 | c.799G>T p.D267Y | Missense Mutation (SNP) | VAF 42/232 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- RRP1B | c.244G>C p.V82L | Missense Mutation (SNP) | VAF 26/308 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.153); called by muse, mutect2
- SLITRK4 | c.545A>G p.H182R | Missense Mutation (SNP) | VAF 21/210 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SQSTM1 | c.1184_1187del p.I395Sfs*67 | Frame Shift Del (DEL) | VAF 36/376 reads (10%) | called by mutect2, pindel
- TP53 | c.700_722del p.Y234Lfs*22 | Frame Shift Del (DEL) | VAF 75/282 reads (27%) | called by mutect2, pindel, varscan2
- TRAPPC8 | c.2329C>A p.L777I | Missense Mutation (SNP) | VAF 11/180 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.206); called by muse, mutect2
- WLS | c.1573G>A p.V525M | Missense Mutation (SNP) | VAF 24/294 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.246); called by muse, mutect2
- ZDHHC8 | c.204G>A p.M68I | Missense Mutation (SNP) | VAF 13/149 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.292); called by muse, mutect2
- ZNF383 | c.119G>A p.G40D | Missense Mutation (SNP) | VAF 5/91 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.006); called by muse, mutect2
- ADAMTS15 | c.1344C>T p.C448= | Silent (SNP) | VAF 8/100 reads (8%) | catalogued as rs376836072; called by muse, mutect2
- ADGRA1 | c.378G>A p.P126= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as rs368145789; called by mutect2, varscan2
- CRACD | c.3621C>T p.P1207= | Silent (SNP) | VAF 14/253 reads (6%) | catalogued as rs368775360; called by muse, mutect2
- ETNPPL | c.1041G>A p.L347= | Silent (SNP) | VAF 21/254 reads (8%) | catalogued as COSV56596966; called by muse, mutect2
- KMT2D | c.528C>T p.T176= | Silent (SNP) | VAF 16/55 reads (29%) | called by muse, mutect2, varscan2
- KRTAP19-7 | c.24T>C p.Y8= | Silent (SNP) | VAF 17/159 reads (11%) | catalogued as rs779897499; called by muse, mutect2, varscan2
- LSG1 | c.1293T>C p.P431= | Silent (SNP) | VAF 12/158 reads (8%) | called by muse, mutect2
- MEP1B | c.393G>A p.R131= | Silent (SNP) | VAF 10/138 reads (7%) | catalogued as rs1202638015; called by muse, mutect2
- MROH1 | c.4518T>C p.P1506= | Silent (SNP) | VAF 50/355 reads (14%) | called by muse, mutect2, varscan2
- NRG1 | c.135G>A p.Q45= | Silent (SNP) | VAF 15/118 reads (13%) | catalogued as rs767020919; called by muse, mutect2, varscan2
- PCDHA9 | c.1362G>A p.A454= | Silent (SNP) | VAF 92/524 reads (18%) | catalogued as COSV65325237; called by muse, mutect2, varscan2
- PLS3 | c.1500G>A p.Q500= | Silent (SNP) | VAF 12/101 reads (12%) | called by muse, mutect2, varscan2
- PPP2R3B | c.381C>G p.T127= | Silent (SNP) | VAF 28/409 reads (7%) | called by muse, mutect2
- PTCH1 | c.2073C>T p.T691= | Silent (SNP) | VAF 32/402 reads (8%) | catalogued as rs371643436; ClinVar: likely benign; called by muse, mutect2
- TLL1 | c.994C>T p.L332= | Silent (SNP) | VAF 64/349 reads (18%) | called by muse, mutect2, varscan2
- TNXB | c.13344C>T p.N4448= (on ENST00000647633; = p.N4201= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 74/482 reads (15%) | catalogued as rs1203694843; called by muse, varscan2
- USP17L1 | c.522G>A p.K174= | Silent (SNP) | VAF 32/301 reads (11%) | catalogued as rs781714846; called by muse, mutect2, varscan2
- VWA5B1 | c.3246G>A p.T1082= (on ENST00000375079; = p.T1077= on NM_001039500.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as rs956708063; called by muse, mutect2
- WNT10B | c.402G>A p.T134= | Silent (SNP) | VAF 42/494 reads (9%) | called by muse, mutect2
- WWP1 | c.1425G>C p.V475= | Silent (SNP) | VAF 12/140 reads (9%) | called by muse, mutect2
- COMMD8 | c.*48dup | 3'UTR (INS) | VAF 31/255 reads (12%) | called by mutect2, pindel, varscan2
- GLRA3 | c.-8T>A | 5'UTR (SNP) | VAF 29/168 reads (17%) | catalogued as rs752929183; called by muse, mutect2, varscan2
- IRAK3 | c.-32C>T | 5'UTR (SNP) | VAF 20/204 reads (10%) | called by muse, mutect2
- SMOC1 | c.584-22C>T | Intron (SNP) | VAF 36/309 reads (12%) | catalogued as rs935305877; called by muse, mutect2, varscan2
- SNORD113-8 | n.72C>A | RNA (SNP) | VAF 7/69 reads (10%) | called by muse, mutect2
- TCEA1 | c.232+24A>C | Intron (SNP) | VAF 36/103 reads (35%) | called by muse, mutect2, varscan2
- THSD4 | c.-80+14228G>T | Intron (SNP) | VAF 79/334 reads (24%) | called by muse, mutect2, varscan2
- ZWINT | c.*15G>A | 3'UTR (SNP) | VAF 25/122 reads (20%) | called by muse, mutect2, varscan2
